Somatic mutation profile of tumor specimen 0DJILT from CCDI case PBBXCH, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Ependymoma, NOS; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 1.6 years (568 days).
Specimen 0DJILT: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 251fc540-92f2-4087-b96e-c3b860b203e4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DJIKX (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/643a29ad-f01c-4ac7-b290-cdbc231206b0

The open-access MAF lists 3 somatic variants for this specimen: 2 protein-altering or splice-affecting, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 1, Splice Region 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCB10 | c.1439G>A p.G480E | Missense Mutation (SNP) | VAF 109/346 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV60622113; called by muse, mutect2, varscan2
- HLA-C | c.1016-6C>T | Splice Region (SNP) | VAF 194/642 reads (30%) | called by muse, mutect2, varscan2
- CALCOCO2 | c.825+76T>A | Intron (SNP) | VAF 12/318 reads (4%) | called by muse, mutect2
